Somatic mutation profile of tumor specimen MP2PRT-PATDNM-TMP1-A (aliquot MP2PRT-PATDNM-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATDNM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.4 years (509 days).
Specimen MP2PRT-PATDNM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1049574b-e50d-4867-b959-91fbfc641721.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATDNM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATDNM-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dae4f36-596c-47d1-b5c6-e86659cc9187

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH11 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 122/417 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs757580985, COSV51755495; called by muse, mutect2, varscan2
- SETBP1 | c.814A>G p.N272D | Missense Mutation (SNP) | VAF 107/339 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs1396859510; called by muse, mutect2, varscan2
- SORCS1 | c.3379G>A p.A1127T | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs1419247322, COSV53858086; called by muse, mutect2, varscan2
- SATL1 | c.-138C>A | 5'UTR (SNP) | VAF 176/519 reads (34%) | called by muse, mutect2, varscan2
